Somatic mutation profile of tumor specimen MMRF_1978_2_BM_CD138pos (aliquot MMRF_1978_2_BM_CD138pos_T1_KHS5U_L14864) from MMRF case MMRF_1978, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.1 years (26,709 days).
Specimen MMRF_1978_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ec691186-8065-4dc3-a705-1679c70853dc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1978_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1978_1_PB_WBC_C2_KHS5U_L08117; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e186560-81e4-485f-8bf8-abb37d95e5d1

The open-access MAF lists 106 somatic variants for this specimen: 37 protein-altering or splice-affecting, 14 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 35, Missense Mutation 31, Silent 14, Intron 10, 5'UTR 4, Nonsense Mutation 3, 5'Flank 3, 3'Flank 2, Splice Site 1, Frame Shift Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNB1 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 86/160 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886039396, COSV65570538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 28/82 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACRV1 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs183418543, COSV59755557; called by muse, mutect2, varscan2
- ATP2B3 | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 64/183 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs201753621, COSV54851969; called by muse, mutect2, varscan2
- IGKV1-5 | c.62A>G p.K21R | Missense Mutation (SNP) | VAF 56/148 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565389732; called by muse, varscan2
- IGKV1-8 | c.243G>C p.R81S | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs548841496; called by muse, mutect2, varscan2
- JADE1 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 29/302 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs1176782190; called by muse, mutect2
- KALRN | c.7763G>A p.R2588H (on ENST00000360013 / NM_001024660.4; = p.R891H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.997); catalogued as rs374214808; called by muse, mutect2
- KCNJ4 | c.1178C>T p.A393V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs753595753, COSV57856295; called by muse, mutect2, varscan2
- LGMN | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as rs1488328832, COSV58403475; called by muse, mutect2, varscan2
- N4BP3 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs535658994; called by muse, mutect2, varscan2
- NXF1 | c.801A>G p.L267= | Splice Region (SNP) | VAF 36/106 reads (34%) | catalogued as rs146549860; called by muse, mutect2, varscan2
- PCDHA12 | c.2185G>A p.V729M | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV56549136; called by muse, mutect2, varscan2
- PKNOX2 | c.1102C>T p.Q368* | Nonsense Mutation (SNP) | VAF 19/237 reads (8%) | catalogued as rs778476842; called by muse, mutect2
- RFC1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs190369900; called by muse, varscan2
- TBC1D12 | c.1462A>G p.S488G | Missense Mutation (SNP) | VAF 61/213 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs1237704207; called by muse, mutect2, varscan2
- UBA3 | c.428+1G>A p.X143_splice | Splice Site (SNP) | VAF 23/111 reads (21%) | catalogued as rs1041085271, COSV100734746; called by muse, mutect2, varscan2
- UBXN1 | c.275A>G p.Q92R | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs1471191573, COSV53657439; called by muse, mutect2, varscan2
- ZDHHC14 | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.005); catalogued as rs1226545584; called by muse, mutect2, varscan2
- ZNF724 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 69/599 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV69030484; called by muse, mutect2, varscan2
- ABI3BP | c.1390A>G p.K464E | Missense Mutation (SNP) | VAF 116/240 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ABR | c.1102C>T p.Q368* (on ENST00000302538 / NM_021962.5; = p.Q331* on NM_001092.5) | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- ADGRB3 | c.274C>A p.H92N | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- ATP11A | c.2786T>C p.I929T | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CDX4 | c.761G>A p.S254N | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- DAOA | c.422C>T p.S141L | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ESYT2 | c.2536A>C p.K846Q (on ENST00000613624; = p.K770Q on NM_020728.3) | Missense Mutation (SNP) | VAF 70/292 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- KCNA5 | c.1232T>G p.F411C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KISS1 | c.110A>T p.Q37L | Missense Mutation (SNP) | VAF 46/189 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- MADD | c.1978C>G p.L660V | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- REV3L | c.5475del p.D1826Mfs*5 | Frame Shift Del (DEL) | VAF 111/373 reads (30%) | called by mutect2, pindel, varscan2
- SLC4A7 | c.2239G>A p.G747R | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- TRIO | c.5248G>T p.V1750L | Missense Mutation (SNP) | VAF 22/224 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- USH2A | c.2932G>C p.A978P | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.377); called by muse, mutect2, varscan2
- ZADH2 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2
- ZKSCAN4 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 18/252 reads (7%) | called by muse, mutect2
- ZNF572 | c.964C>A p.H322N | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AC004922.1 | c.831C>T p.R277= | Silent (SNP) | VAF 50/127 reads (39%) | catalogued as rs143044515; called by muse, mutect2, varscan2
- ASIC1 | c.1554G>A p.P518= | Silent (SNP) | VAF 74/241 reads (31%) | catalogued as rs1438234453; called by muse, mutect2, varscan2
- EPHA6 | c.2406G>T p.G802= (on ENST00000389672 / NM_001080448.3; = p.G194= on NM_173655.4) | Silent (SNP) | VAF 27/90 reads (30%) | catalogued as rs781018815; called by muse, mutect2, varscan2
- FILIP1 | c.96C>T p.L32= | Silent (SNP) | VAF 43/345 reads (12%) | catalogued as rs1374101521, COSV99383697; called by muse, mutect2, varscan2
- GPSM1 | c.1767C>T p.H589= | Silent (SNP) | VAF 46/198 reads (23%) | catalogued as rs782156042, COSV52517878; called by muse, mutect2, varscan2
- IGHD6-13 | c.3G>A p.G1= | Silent (SNP) | VAF 51/112 reads (46%) | catalogued as rs782246656; called by muse, mutect2, varscan2
- MYO19 | c.2244T>C p.S748= (on ENST00000614623 / NM_001163735.1; = p.S548= on NM_025109.5) | Silent (SNP) | VAF 60/222 reads (27%) | called by muse, mutect2, varscan2
- PLXNB1 | c.2550C>T p.P850= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs774347842; called by muse, mutect2, varscan2
- RTL1 | c.1353C>T p.Y451= | Silent (SNP) | VAF 55/183 reads (30%) | catalogued as rs539590557; called by muse, mutect2, varscan2
- TP73 | c.693C>T p.T231= | Silent (SNP) | VAF 37/145 reads (26%) | catalogued as rs772632573; called by muse, mutect2, varscan2
- WDR81 | c.5754C>T p.S1918= (on ENST00000409644 / NM_001163809.2; = p.S867= on NM_152348.4) | Silent (SNP) | VAF 59/155 reads (38%) | catalogued as COSV100488642; called by muse, mutect2, varscan2
- XDH | c.1551C>T p.F517= | Silent (SNP) | VAF 32/116 reads (28%) | called by muse, mutect2, varscan2
- ZKSCAN4 | c.444G>C p.G148= | Silent (SNP) | VAF 19/252 reads (8%) | called by muse, mutect2
- ZNF26 | c.48C>T p.F16= | Silent (SNP) | VAF 35/424 reads (8%) | called by muse, mutect2
- ABCA8 | c.797+162G>A | Intron (SNP) | VAF 8/33 reads (24%) | catalogued as rs541422233; called by muse, mutect2, varscan2
- ACTR8 | c.*54G>A | 3'UTR (SNP) | VAF 78/287 reads (27%) | called by muse, mutect2, varscan2
- C3orf14 | chr3:62333804 T>A | 3'Flank (SNP) | VAF 22/80 reads (28%) | catalogued as rs539908685, COSV51706720; called by muse, varscan2
- CBFA2T2 | c.*1183C>T | 3'UTR (SNP) | VAF 46/118 reads (39%) | catalogued as rs575864344; called by muse, mutect2, varscan2
- CC2D1B | c.*298G>A | 3'UTR (SNP) | VAF 28/286 reads (10%) | catalogued as rs760482574; called by muse, mutect2
- CD79B | c.*292G>A | 3'UTR (SNP) | VAF 45/235 reads (19%) | called by muse, mutect2, varscan2
- CNKSR2 | c.*870T>C | 3'UTR (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- CRISPLD1 | c.*503del | 3'UTR (DEL) | VAF 20/73 reads (27%) | catalogued as rs1306035305; called by mutect2, pindel, varscan2
- CXXC4 | c.*2073T>G | 3'UTR (SNP) | VAF 13/53 reads (25%) | called by muse, varscan2
- DLL4 | c.394+59A>T | Intron (SNP) | VAF 28/106 reads (26%) | catalogued as rs758333373; called by muse, mutect2, varscan2
- DPYSL5 | c.*1970G>T | 3'UTR (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
- EQTN | c.-39G>C | 5'UTR (SNP) | VAF 26/435 reads (6%) | called by muse, mutect2
- FAT4 | c.*212T>G | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- FERMT2 | c.*4G>A | 3'UTR (SNP) | VAF 22/105 reads (21%) | catalogued as COSV100448597; called by muse, mutect2, varscan2
- FSCB | c.*190C>T | 3'UTR (SNP) | VAF 15/97 reads (15%) | called by muse, mutect2, varscan2
- GYS2 | c.*368C>T | 3'UTR (SNP) | VAF 28/104 reads (27%) | called by muse, mutect2, varscan2
- H6PD | c.*5904G>C | 3'UTR (SNP) | VAF 59/176 reads (34%) | called by muse, mutect2, varscan2
- HEBP2 | chr6:138403599 G>C | 5'Flank (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- HHIPL1 | c.*2186C>T | 3'UTR (SNP) | VAF 43/100 reads (43%) | catalogued as rs777755543; called by muse, mutect2, varscan2
- HLX | c.-384A>G | 5'UTR (SNP) | VAF 73/200 reads (37%) | called by muse, mutect2, varscan2
- HTRA1 | c.*319T>G | 3'UTR (SNP) | VAF 36/114 reads (32%) | called by muse, mutect2, varscan2
- ICAM3 | c.1442-23G>A | Intron (SNP) | VAF 22/316 reads (7%) | called by muse, mutect2
- ITPKB | c.*2143G>T | 3'UTR (SNP) | VAF 17/94 reads (18%) | called by muse, varscan2
- KBTBD3 | c.-140C>T | 5'UTR (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- KIAA1958 | c.1172-27345C>T | Intron (SNP) | VAF 24/202 reads (12%) | catalogued as rs1469345287; called by muse, mutect2, varscan2
- KIF3B | c.*415A>G | 3'UTR (SNP) | VAF 87/197 reads (44%) | called by muse, mutect2, varscan2
- LANCL2 | c.*741A>G | 3'UTR (SNP) | VAF 41/153 reads (27%) | called by muse, mutect2, varscan2
- MIR5195 | chr14:106851258 C>T | 5'Flank (SNP) | VAF 67/232 reads (29%) | catalogued as rs147455610; called by muse, mutect2, varscan2
- NEUROD1 | c.*26G>A | 3'UTR (SNP) | VAF 27/74 reads (36%) | catalogued as COSV54548040; called by muse, mutect2, varscan2
- NLGN3 | c.*996A>T | 3'UTR (SNP) | VAF 15/62 reads (24%) | catalogued as rs1459651475; called by mutect2, varscan2
- PDXK | c.*3119C>G | 3'UTR (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- PPM1H | c.*2121C>T | 3'UTR (SNP) | VAF 9/117 reads (8%) | called by muse, mutect2
- PRDM2 | c.5036+5118G>A | Intron (SNP) | VAF 35/113 reads (31%) | called by muse, mutect2, varscan2
- PTAR1 | c.*1675_*1682del | 3'UTR (DEL) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- RELCH | c.*265T>A | 3'UTR (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2, varscan2
- RPRD2 | c.436+317T>A | Intron (SNP) | VAF 14/65 reads (22%) | called by muse, mutect2, varscan2
- RPS6KC1 | c.*2065_*2066del | 3'UTR (DEL) | VAF 5/63 reads (8%) | catalogued as rs1272222861; called by pindel, varscan2
- SAR1B | c.*2910T>C | 3'UTR (SNP) | VAF 19/88 reads (22%) | called by muse, mutect2, varscan2
- SEPHS2 | c.*447T>G | 3'UTR (SNP) | VAF 17/58 reads (29%) | called by muse, mutect2, varscan2
- SETD6 | chr16:58515507 G>A | 5'Flank (SNP) | VAF 12/23 reads (52%) | catalogued as COSV50753669; called by muse, mutect2, varscan2
- SLC2A12 | c.*1999C>T | 3'UTR (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- SNTB2 | c.*5402A>G | 3'UTR (SNP) | VAF 10/94 reads (11%) | catalogued as rs1337556012; called by muse, mutect2
- SRI | chr7:88202605 A>C | 3'Flank (SNP) | VAF 62/145 reads (43%) | called by muse, mutect2, varscan2
- TBL2 | c.598+58A>G | Intron (SNP) | VAF 25/96 reads (26%) | catalogued as rs1398532959; called by muse, mutect2, varscan2
- TFAP2E | c.562+2462G>A | Intron (SNP) | VAF 32/106 reads (30%) | called by muse, mutect2, varscan2
- TMED7-TICAM2 | c.439-22G>A | Intron (SNP) | VAF 38/158 reads (24%) | called by muse, mutect2, varscan2
- TMEM260 | c.*1858C>G | 3'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- TNFRSF10D | c.-58C>G | 5'UTR (SNP) | VAF 34/450 reads (8%) | called by muse, mutect2
- TNS3 | c.*1980T>G | 3'UTR (SNP) | VAF 38/173 reads (22%) | called by muse, mutect2, varscan2
- TPMT | c.*2085G>A | 3'UTR (SNP) | VAF 95/186 reads (51%) | called by muse, mutect2, varscan2
- TTC3P1 | n.4788A>G | RNA (SNP) | VAF 30/108 reads (28%) | called by muse, mutect2
- UNC5C | c.*1381G>A | 3'UTR (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- ZBTB7C | c.*46C>T | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2
- ZNF365 | c.*2075C>T | 3'UTR (SNP) | VAF 7/116 reads (6%) | called by muse, mutect2
- ZP3 | c.313-147G>C | Intron (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
